Somatic mutation profile of tumor specimen TCGA-KL-8342-01A (aliquot TCGA-KL-8342-01A-11D-2310-10) from TCGA case TCGA-KL-8342, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 45.3 years (16,550 days).
Specimen TCGA-KL-8342-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8ca7838-5f76-4653-9f65-04caa52fb94b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8342-11A (Solid Tissue Normal), aliquot TCGA-KL-8342-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59cfcd3e-4834-492b-8373-f9001d5d9663

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF3 | c.3667G>A p.A1223T | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs138104794; called by muse, mutect2, varscan2
- AIFM1 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99780908; called by muse, mutect2
- ERCC4 | c.2444A>T p.E815V | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100318769; called by muse, mutect2
- FGA | c.1800C>G p.S600R | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100120252; called by muse, mutect2
- RNF115 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as rs1382292559; called by muse, mutect2, varscan2
- TSC2 | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs796053492, CM091925; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- USP19 | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV60045373; called by muse, mutect2
- WDR72 | c.1261T>C p.C421R | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1187127400; called by muse, mutect2, varscan2
- ZCCHC4 | c.960del p.F320Lfs*19 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as rs760215323; called by mutect2, pindel
- PLEKHM1 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHMT1 | c.1166G>T p.C389F | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC9A5 | c.1711C>A p.L571M | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ERBB3 | c.2598G>A p.L866= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- GALE | c.1044C>T p.A348= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- MAMLD1 | c.933A>T p.A311= | Silent (SNP) | VAF 51/69 reads (74%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2012G>A | Intron (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
